Somatic mutation profile of tumor specimen MP2PRT-PASWZC-TMP1-A (aliquot MP2PRT-PASWZC-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASWZC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.8 years (3,217 days).
Specimen MP2PRT-PASWZC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ba4e144-4594-4bd5-8a37-8d25b57e5e9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASWZC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASWZC-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/559c04ac-6fd8-468f-bbcf-3a69855b1fbb

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 7, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRSK1 | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 128/435 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as rs1442587293, COSV58668637; called by muse, mutect2, varscan2
- PAX5 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 147/294 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs757277825; called by muse, mutect2, varscan2
- ROR2 | c.2065G>A p.V689I | Missense Mutation (SNP) | VAF 106/507 reads (21%) | catalogued as rs1205330622, COSV104424229, COSV99058612; called by muse, mutect2, varscan2
- SBF2 | c.3935G>A p.R1312Q | Missense Mutation (SNP) | VAF 111/369 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs768571931, COSV56292746; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKD1 | c.1805A>T p.H602L | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- USH2A | c.7042A>G p.R2348G | Missense Mutation (SNP) | VAF 168/443 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZNF98 | c.1652G>T p.C551F | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- C8orf34 | c.849C>T p.P283= | Silent (SNP) | VAF 98/446 reads (22%) | catalogued as COSV61389536; called by muse, mutect2, varscan2
- FANCB | c.1587G>A p.K529= | Silent (SNP) | VAF 190/503 reads (38%) | called by muse, mutect2, varscan2
- NPIPB6 | c.45T>C p.H15= | Silent (SNP) | VAF 131/620 reads (21%) | called by muse, mutect2, varscan2
- PTPRS | c.2877C>T p.N959= | Silent (SNP) | VAF 58/457 reads (13%) | catalogued as rs541561864; called by muse, mutect2, varscan2
- SLC6A8 | c.663G>A p.L221= | Silent (SNP) | VAF 52/245 reads (21%) | called by muse, mutect2, varscan2
- USP9X | c.3471T>C p.L1157= | Silent (SNP) | VAF 156/513 reads (30%) | called by muse, mutect2, varscan2
